Gene-level copy-number profile of tumor specimen 1105266 from CPTAC case C685110, project CPTAC-3 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Intraductal carcinoma, NOS; Tissue or organ of origin: Breast, NOS.
Specimen 1105266: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d1821e34-fdf6-4708-880c-913ea9d7c159.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105277 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/013e58f7-63da-4225-9c20-5fb0446ea555

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 29; copy number 2: 20,148; copy number 3: 8,015; copy number 4: 22,454; copy number 5: 1,947; copy number 6: 4,230; copy number 7: 259; copy number 8: 1,017; copy number 9: 213; copy number 10: 33; copy number 11: 9; copy number 12: 6; copy number 13: 6.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,606,291–161,608,217, 1 gene (within-gene range 0–1): HSPA7.
- chr1:161,623,196–161,631,963, 1 gene (within-gene range 0–1): FCGR3B.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr5:125,265,528–125,265,651, 1 gene: HMGB1P22.
- chr8:108,871,128–109,063,417, 1 gene: AC104248.1.
- chr9:14,081,843–14,910,995, 14 genes: NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P.
- chr9:14,921,337–15,019,729, 2 genes (within-gene range 0–2): LDHAP4, AL592293.1.
- chr11:129,279–186,136, 2 genes (within-gene range 0–2): AC069287.3, RNU6-447P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 267 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,749,342–248,527,337, 109 genes, copy number 9 (broad region; genes not listed).
- chr1:248,649,838–248,937,043, 16 genes, copy number 10: OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr3:184,135,038–184,146,127, 1 gene, copy number 9 (within-gene range 4–9): EIF2B5.
- chr3:184,155,377–184,173,614, 1 gene, copy number 9 (within-gene range 4–9): DVL3.
- chr3:184,299,198–186,362,234, 39 genes, copy number 9: PSMD2, EIF4G1, SNORD66, FAM131A, CLCN2, POLR2H, THPO, CHRD, LINC02054, AC128714.2, LINC01839, LINC01840, EPHB3, MAGEF1, AC107294.2, LINC02069, AC107294.3, AC107294.1, VPS8, C3orf70, EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4, TMEM41A, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B, NMRAL2P, ETV5, Metazoa_SRP, ETV5-AS1, DGKG.
- chr7:192,571–2,614,733, 62 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr7:2,906,142–3,043,867, 1 gene, copy number 12 (within-gene range 6–12): CARD11.
- chr7:2,999,094–3,302,452, 5 genes, copy number 12 (within-gene range 6–12): RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1.
- chr7:6,754,109–6,799,365, 1 gene, copy number 9 (within-gene range 6–9): RSPH10B2.
- chr7:37,585,500–38,025,695, 7 genes, copy number 10–13: NECAP1P1, GPR141, EPDR1, GPR141BP, AC018634.1, NME8, SFRP4.
- chr7:40,964,667–41,133,507, 2 genes, copy number 10: LINC01450, LINC01449.
- chr11:107,502,727–108,121,684, 14 genes, copy number 10 (within-gene range 8–10): ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1.
- chr17:73,164,977–73,312,005, 9 genes, copy number 11: AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4.

Autosomal genes at a single copy (total copy number 1): 29. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
